Somatic mutation profile of tumor specimen TCGA-EJ-5502-01A (aliquot TCGA-EJ-5502-01A-01D-1576-08) from TCGA case TCGA-EJ-5502, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 50.5 years (18,447 days).
Specimen TCGA-EJ-5502-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31893451-7317-4703-afb7-318c8c5397ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5502-10A (Blood Derived Normal), aliquot TCGA-EJ-5502-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ce916de-d5f6-4228-ad0c-b333e3a20a22

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACBD7 | c.256T>G p.Y86D | Missense Mutation (SNP) | VAF 21/268 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV62252543; called by muse, mutect2
- HSD17B3 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 17/328 reads (5%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs539588932, COSV64557149; called by muse, mutect2
- OR7A17 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.045); catalogued as rs375822511; called by muse, mutect2
- OTOF | c.2590C>T p.R864C (on ENST00000272371 / NM_194248.3; = p.R117C on NM_004802.4) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs150070091; ClinVar: uncertain significance; called by muse, mutect2
- PCDHB14 | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 13/156 reads (8%) | catalogued as COSV53386784, COSV53389653; called by muse, mutect2
- RAG1 | c.2596G>A p.V866M | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55025583; called by muse, mutect2
- ZFPM2 | c.1805C>T p.T602I | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as rs779192516, COSV65873948; called by muse, mutect2
- FZD3 | c.834A>T p.T278= | Silent (SNP) | VAF 10/230 reads (4%) | catalogued as COSV53535719; called by muse, mutect2
